Somatic mutation profile of tumor specimen 0DL0JW from CCDI case PBBYTM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sclerosing stromal tumor; Tissue or organ of origin: Ovary; Age at diagnosis: 15.3 years (5,584 days).
Specimen 0DL0JW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcdcdbd3-f4d6-427b-9d47-93e2c31b9b06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL0IU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82f2265b-60fc-4e15-8ed9-f150ff0ddd17

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STYK1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 140/430 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs772530382, COSV50013479; called by muse, mutect2
- ZNF619 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 165/450 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs752578921, COSV59030560; called by muse, mutect2, varscan2
- FAM83F | c.1101G>A p.S367= | Silent (SNP) | VAF 31/416 reads (7%) | catalogued as rs373307669; called by muse, mutect2
- OR52B4 | c.222C>G p.V74= | Silent (SNP) | VAF 27/1063 reads (3%) | called by muse, mutect2
